Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IS, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IS-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A DISTAL PANCREAS AND SPLEEN, PANCREATECTOMY AND SPLENECTOMY:
- Pancreatic well differentiated neuroendocrine carcinoma
- See key pathologic findings.
- Thirty-two benign lymph nodes (0/32)

I, the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed
Out by

Comment

The mitotic count is 1 per 10 high power fields; this count corresponds to a low-grade neuroendocrine carcinoma (G1).

A Ki67 immunostain is pending. A report will follow.

Key Pathological Findings

Tumor type: neuroendocrine carcinoma
Tumor location: pancreas, distal
Histologic grade: low-grade
Tumor size: 8 x 4.7 x 3.0 cm
Vascular invasion: absent
Perineural invasion: absent
Extrapaneatic extension (for pancreatic tumors only): absent
Surgical margins: uninvolved
Extent of invasion: The tumor is confined within its capsule
Non-neoplastic pancreas: Focal chronic pancreatitis
Lymph nodes (total): 0/32
TNM stage: pT2, pN0

Specimen(s) Received

A DISTAL PANCREAS AND SPLEEN FS

Clinical History

Pancreatic neuroendocrine tumor.

ICD-O-3

Carcinoma, neuroendocrine NOS
8.246/3

Site: Pancreas body 251

Op 4/16/14

[page 2 of 2]
Preoperative Diagnosis

Pancreatic neuroendocrine tumor.

Intraoperative Consultation

FSA: DISTAL PANCREAS AND SPLEEN:

Distal pancreas margin:

Negative for tumor.

Comment: This frozen section diagnosis/result is communicated to and acknowledged by Dr.

I, MD, have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. Specimen A is received fresh for frozen section consultation, labeled "distal pancreas and spleen" and consists of a 571.3 gram distal pancreas with attached spleen. The pancreas is 14.5 x 5.0 x 4.0 cm. The spleen is 17.0 x 12.0 x 4.7 cm. Within the pancreas is an 8.0 x 4.7 x 3.0 cm, partially encapsulated, soft tan and orange, lobulated mass. The mass extends the full length of the pancreas and is 0.7 cm from the pancreatic margin. The mass has a surrounding, thin membranous lining, which is inked blue. There is a small amount of normal pancreatic tissue surrounding the mass. The remaining pancreas is yellow, lobulated, admixed with thick, white fibrous stroma. The spleen is homogeneous, dark red, and slightly nodular. No mass or other lesions are identified. The pancreatic margin is sectioned tangentially, frozen and entirely submitted in FSA1. Additional representative sections are submitted as follows:

- A2: Mass perpendicular to margin.
- A3-A4: Mass with adjacent normal pancreas.
- A5-A6: Mass with surrounding thin membrane.
- A7-A8: Mass.
- A9: Mass with duct
- A10: Normal pancreas.
- A11: Normal spleen.
- A12: 7 possible lymph nodes.
- A13: 7 possible lymph nodes.
- A14: 7 possible lymph nodes, 2 differentially inked and bisected.
- A15: 5 possible lymph nodes.
- A16: 4 possible lymph nodes, 2 differentially inked and sectioned.
- A17-A18: 1 possible lymph node, sectioned.

A portion of tissue is submitted to Tissue Procurement Laboratory.

Source: NCI Genomic Data Commons file c5f6b496-ff6a-4fba-be6e-f1af46ecb531 (TCGA-3A-A9IS.BC3170CA-A046-4D78-9CC6-36C5B70A9C4C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).